Surgical pathology report (de-identified scan), TCGA case TCGA-75-5126, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site Ontario Institute for Cancer Research (OICR), specimen TCGA-75-5126-01A (Primary Tumor).

75-5126

Sample Collection Details

Histology and staging

Sample Number	Sample Type	Sample Preparation	Site of Tissue	Diagnosis	Year of Sample Collection	Age at Sample Collection (yrs)	Sample Comments	Days to Procedure Date	Days to Diagnosis	Type of Procedure	Site of Primary (Histology)	Tumour Size (cm)	Histology	Grade/Differentiation	Pathological T	Pathological N	Clinical M	YALCSG Stage	Histology Comments	Slide Image
	TUMOUR	FF	LUL	Adenocarcinoma						RESECT	LUL	7.10	03	II	T3,N0S	N2	M0		The tumour was positive for CK7 and TTF-1.	
	SUFFY	FF		Adenocarcinoma						RESECT	LUL	7.10	03	II	T3,N0S	N2	M0		The tumour was positive for CK7 and TTF-1.	

Source: NCI Genomic Data Commons file fe30acfc-4eb0-4b47-a002-d7a1ebf9f15f (TCGA-75-5126.ED7F326C-D2F5-46EF-BD92-ED2D0F81BE26.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).